Somatic mutation profile of tumor specimen MP2PRT-PAULEB-TMP1-A (aliquot MP2PRT-PAULEB-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAULEB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,748 days).
Specimen MP2PRT-PAULEB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d119e3f3-19ff-4541-a8f5-b56bba6384be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAULEB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAULEB-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13236a40-1cb4-458f-9b0f-5448e8ebe792

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK1 | c.2108G>T p.S703I | Missense Mutation (SNP) | VAF 103/284 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61087718, COSV61088652; called by muse, mutect2, varscan2
- KLK9 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 206/510 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.37); catalogued as rs766128169; called by muse, mutect2, varscan2
- PTPRR | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 140/372 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.317); catalogued as rs370625173; called by muse, varscan2
- GNB1 | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 99/309 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PARP14 | c.4081C>T p.Q1361* | Nonsense Mutation (SNP) | VAF 139/357 reads (39%) | called by muse, mutect2, varscan2
- SIN3B | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 141/403 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- FAM47B | c.855G>A p.P285= | Silent (SNP) | VAF 217/545 reads (40%) | catalogued as rs377063124, COSV61452475; called by muse, mutect2, varscan2
